FM case AD844 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/e8985d6c-1ca2-4df7-83eb-a5876757b1d9

Male, 46.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3). Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
